Gene-level copy-number profile of tumor specimen TCGA-SR-A6MT-01A from TCGA case TCGA-SR-A6MT, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 57.3 years (20,944 days).
Specimen TCGA-SR-A6MT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.cf00d4fc-cebe-4013-b4ca-eb941c0d62d6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SR-A6MT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 355 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07e7870f-5189-4daf-ae8e-bb70fe79b711

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 10; copy number 2: 35,319; copy number 3: 18,490; copy number 4: 5,847; copy number 5: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SR-A6MT-01A-11D-A35H-01): tumor purity 0.9, ploidy 2.5, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 82 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–19,936,757, 82 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
